Gene-level copy-number profile of tumor specimen TCGA-HU-8243-01A from TCGA case TCGA-HU-8243, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 66.2 years (24,187 days).
Specimen TCGA-HU-8243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.71c0a224-5953-4b59-a49c-b7aa1e959f1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-8243-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cbcb8f5e-0bf2-40f6-a0bc-03587851277e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,350; copy number 2: 19,201; copy number 3: 20,207; copy number 4: 12,892; copy number 5: 3,704; copy number 6: 1,029; copy number 7: 1,237; copy number 8: 77; copy number 9: 42; copy number 11: 12; copy number 12: 7; copy number 13: 12; copy number 19: 22; copy number 50: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-8243-01A-11D-2338-01): tumor purity 0.58, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,431 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,419,444–55,595,006, 22 genes, copy number 50: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.
- chr7:117,882,859–121,297,442, 21 genes, copy number 7 (within-gene range 4–7): AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241.
- chr8:124,488,485–124,539,458, 1 gene, copy number 7 (within-gene range 5–7): TATDN1.
- chr8:124,508,515–145,066,685, 381 genes, copy number 7 (broad region; genes not listed).
- chr10:1,957,589–2,618,739, 12 genes, copy number 11: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1.
- chr11:4,482,646–5,207,308, 54 genes, copy number 9–13: OR52K1, OR52M2P, OR52M1, C11orf40, OR52I2, OR52I1, TRIM68, OR51D1, OR51E1, OR51A9P, OR51E2, OR51C1P, MMP26, OR51F5P, OR51C4P, KRT8P49, OR51F3P, OR51F4P, SNORA62, OR51F1, OR51N1P, OR52Y1P, OR52R1, OR51F2, OR51A8P, OR51S1, OR51H1, OR51H2P, OR51T1, OR51A6P, OR51A7, OR51G2, OR51G1, OR51A3P, OR51A4, OR51A2, OR51A5P, OR51L1, OR51P1P, OR52J2P, OR52J3, OR52E2, OR52E1, OR52S1P, OR52E3P, OR52J1P, AC113331.1, OR52A4P, OR52A5, OR52A1, OR51A1P, OR52Z1, OR51V1, AC104389.2.
- chr11:5,596,109–6,474,459, 49 genes, copy number 8: TRIM6, TRIM6-TRIM34, TRIM34, TRIM5, TRIM22, OR52U1P, OR52P1P, OR56B1, OR52N4, OR56B2P, OR52N5, OR52N1, OR52N3P, OR52N2, OR52E6, OR52E8, OR52E7P, OR52E4, OR52E5, OR52Q1P, OR56A3, OR56A5, OR52L1, KRT18P58, OR56A4, RNA5SP329, OR56A1, OR56A7P, OR52L2P, OR52X1P, OR56B4, AC022762.1, OR56B3P, OR52B1P, OR52B2, OR52W1, AC022762.2, C11orf42, FAM160A2, CNGA4, CCKBR, AC068733.2, CAVIN3, AC068733.3, AC068733.1, SMPD1, APBB1, HPX, TRIM3.
- chr18:20,946,906–23,531,822, 57 genes, copy number 8–19: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1.
- chr20:33,993,646–34,108,308, 1 gene, copy number 7 (within-gene range 4–7): RALY.
- chr20:34,049,119–64,313,132, 777 genes, copy number 7 (broad region; genes not listed).
- chr22:25,448,105–27,419,713, 56 genes, copy number 7 (within-gene range 5–7): CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1.

Autosomal genes at a single copy (total copy number 1): 373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
